Surgical pathology report (de-identified scan), TCGA case TCGA-06-5858, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-5858-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

Surgical Pathology Report

TCGA--06-5858

[REDACTED]

CLINICAL HISTORY

[REDACTED] has a 6.5 cm, irregularly nodular, ring enhancing mass with restricted diffusion in the left frontal lobe, with probable involvement of the corpus callosum. There is also small clival lytic lesion.

OPERATIVE DIAGNOSES

Left frontal brain tumor

Operation/Specimen: A: Left frontal brain tumor, biopsy
B: Left frontal brain tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, frontal, biopsy and excisional biopsy:

1. Glioblastoma.
2. MIB-1 proliferation index: 65%.
- See Microscopy Description and Comment.

COMMENT

The sections contain portions of a glial neoplastic proliferation that focally infiltrates and extensively effaces the brain. The neoplasm has nuclear anaplastic features, mitotic activity, microvascular cellular proliferation and necrosis, and extensive tumor necrosis, frequently with pseudopalisading.

The MIB-1 proliferation index is very high (65%).

The neoplasm is a glioblastoma, WHO IV.

Results of Molecular testing will be reported later.

[REDACTED]

[page 2 of 5]
=====

PROCEDURES/ADDENDA

PCR for EGFR variant III mutation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from tissue block

H slide was examined and no microdissection was needed.

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is

commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct

subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been

shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor

suppressor protein PTEN is intact. RNA is extracted from formalin fixed,

paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is

then amplified using standard PCR technique for DNA templates. PCR products

are detected by gel electrophoresis. The limit of detection of this assay has

been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

[page 3 of 5]
provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from microdissected tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or

extensive tissue necrosis, may preclude the detection of methylated MGMT

promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved

for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

[page 4 of 5]
INTRA-OPERATIVE CONSULTATION

A.

Left frontal brain tumor, biopsy: Glioblastoma, 1 block, [REDACTED]
Frozen

section performed at [REDACTED]

[REDACTED] and called to the Physician of record on

[REDACTED] Telepathology utilized to [REDACTED]

GROSS DESCRIPTION

A.

Left frontal brain tumor, biopsy

CONTAINER LABEL: left frontal brain tumor.

FIXATIVE: Formalin. NO. PIECES: 3. SIZE/VOL: aggregate to 1.6 x 1 x
0.2 cm.

CASSETTES: 1, [REDACTED]

B.

Left frontal brain tumor, excision biopsy

CONTAINER LABEL: left frontal brain tumor

FIXATIVE: formalin

GENERAL: Received are pink-tan to white fragments, aggregating to 2.2
x 1.1 x

0.3 cm.

SECTIONS: 1, [REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates prominent
gliofibrillogenesis by
the neoplastic cells. A great majority of neoplastic cells over
express the
p53 protein. With the MIB-1 there is a proliferation index of about
65%.

ICD-9(s):

237.5 237.5 191.9

Histo Data

Part A: Left frontal brain tumor, biopsy

Taken: [REDACTED] Received: [REDACTED]

Stain/cnt

Block

Ordered

Comment

[page 5 of 5]
FS H/E x 1 1
H/E x 1 1

Part B: Left frontal brain tumor, excision biopsy

Taken:	Received:		
Stain/cnt	Block Ordered Comment		
EGFR VIII-slides x 1	1		
mGFAP-DA x 1	1		
H/E x 1	1		
MGMT-slides x 1	1		
MIB1-DA x 1	1		
P53D07 x 1	1		

*** End of Report ***

Source: NCI Genomic Data Commons file d30a72cb-1927-4aa2-a335-1658c67448c8 (TCGA-06-5858.2D08DAA7-75AE-4FE0-8C06-311B585DE812.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).